Somatic mutation profile of tumor specimen MMRF_1655_1_PB_CD138pos (aliquot MMRF_1655_1_PB_CD138pos_T12_KHS5U_L08653) from MMRF case MMRF_1655, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.4 years (23,145 days).
Specimen MMRF_1655_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fe4d3f9-9099-4671-99eb-c89890de2514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1655_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1655_1_PB_CD3pos_C2_KBS5U_L05372; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f386826-f075-4b0e-a0a9-df6f6a8a9512

The open-access MAF lists 21 somatic variants for this specimen: 6 protein-altering or splice-affecting, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 7, Intron 4, Missense Mutation 3, 5'Flank 2, Nonsense Mutation 2, Splice Region 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as CD097511; called by muse, mutect2
- KCNA6 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV54976729; called by muse, mutect2, varscan2
- LCA5L | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99903616; called by muse, mutect2, varscan2
- ADAMTS7 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- NPAS1 | c.695G>C p.S232T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VDAC1 | c.552-6T>G | Splice Region (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- ALDH4A1 | chr1:18902692 del A | 5'Flank (DEL) | VAF 45/101 reads (45%) | called by mutect2, varscan2
- C4orf46 | c.*1723A>G | 3'UTR (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- COL5A1 | c.3367-204C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1469128192; called by muse, mutect2
- CSF2RA | c.810+115C>T | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as rs58223116; called by muse, varscan2
- FREM1 | c.-118T>C | 5'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as COSV66527891; called by mutect2, varscan2
- G3BP1 | c.*7555C>A | 3'UTR (SNP) | VAF 14/70 reads (20%) | catalogued as COSV67606556; called by muse, mutect2
- INTS11 | c.429+620T>C | Intron (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2
- LRTM1 | c.*127_*131del | 3'UTR (DEL) | VAF 7/43 reads (16%) | catalogued as rs781760115; called by pindel, varscan2
- MRPL40 | c.53+156C>T | Intron (SNP) | VAF 11/31 reads (35%) | called by mutect2, varscan2
- PTGFR | c.*305T>A | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- RUNDC3B | c.*597C>T | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- TMEM258 | chr11:61792749 G>A | 5'Flank (SNP) | VAF 3/36 reads (8%) | catalogued as rs1425554663; called by muse, mutect2
- YEATS2 | c.*2021A>G | 3'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs956120112; called by muse, mutect2, varscan2
- YY1 | c.*678_*681del | 3'UTR (DEL) | VAF 9/25 reads (36%) | catalogued as rs1365813463; called by mutect2, pindel, varscan2
- ZNF566 | chr19:36445542 G>A | 3'Flank (SNP) | VAF 16/37 reads (43%) | catalogued as rs927955514; called by muse, mutect2, varscan2
